Somatic mutation profile of tumor specimen MP2PRT-PARSUA-TMP1-A (aliquot MP2PRT-PARSUA-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PARSUA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.3 years (1,942 days).
Specimen MP2PRT-PARSUA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b5bd10f-176c-4369-a96b-5cceb81d5fd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARSUA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARSUA-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e0255c4-c4b7-4f8f-bcf9-8fc0d2e0917a

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, In Frame Ins 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 102/466 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs202049536, COSV60926525; called by muse, mutect2, varscan2
- LRTM1 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 127/359 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs201588903; called by muse, mutect2, varscan2
- MYT1L | c.3484C>T p.R1162C | Missense Mutation (SNP) | VAF 65/213 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.827); catalogued as rs772863694, COSV67701968; called by muse, mutect2, varscan2
- NEB | c.17947C>T p.R5983C | Missense Mutation (SNP) | VAF 140/352 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs762019205; called by muse, mutect2, varscan2
- PPP1R12A | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 104/281 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV54107443; called by muse, mutect2, varscan2
- TRIML2 | c.298A>T p.N100Y | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100456254; called by muse, mutect2, varscan2
- F5 | c.2972A>G p.K991R | Missense Mutation (SNP) | VAF 170/396 reads (43%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP1B | c.1350_1351insGGGGGG p.E450_F451insGG | In Frame Ins (INS) | VAF 85/286 reads (30%) | called by mutect2, pindel, varscan2
- MAVS | c.17A>G p.D6G | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- MRPS14 | c.320G>T p.S107I | Missense Mutation (SNP) | VAF 12/396 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2Z1 | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 138/330 reads (42%) | called by muse, mutect2, varscan2
- SAP30L | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 26/625 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.23); called by muse, mutect2
- TTN | c.18161G>C p.G6054A (on ENST00000591111; = p.G5127A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/267 reads (15%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAT3 | c.720C>T p.A240= | Silent (SNP) | VAF 136/606 reads (22%) | catalogued as rs762366523; called by muse, mutect2, varscan2
- IGKV1D-13 | c.330T>C p.C110= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs1470006811; called by muse, varscan2
- MED16 | c.858G>A p.L286= | Silent (SNP) | VAF 53/255 reads (21%) | called by muse, mutect2, varscan2
- PCARE | c.2691C>T p.T897= | Silent (SNP) | VAF 30/481 reads (6%) | catalogued as rs767685634, COSV59054838; called by muse, mutect2
- TM2D2 | c.228-51G>A | Intron (SNP) | VAF 56/233 reads (24%) | catalogued as rs183919326, COSV101166273, COSV65959612; called by muse, mutect2, varscan2
